Somatic mutation profile of tumor specimen 0DT4I9 from CCDI case PBCINB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.0 years (5,837 days).
Specimen 0DT4I9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a3c270f-a1f4-4b4d-9449-759340eb7136.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT4I5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bc95457-40e2-4bed-8570-cca846e46254

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1966A>G p.K656E (on ENST00000447712 / NM_023110.3; = p.K654E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 278/973 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869320694, COSV58327161, COSV58340654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 64/1704 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- FGFR1 | c.1693T>C p.S565P (on ENST00000447712 / NM_023110.3; = p.S563P on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/556 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CTNND1 | c.27C>T p.T9= | Silent (SNP) | VAF 222/834 reads (27%) | catalogued as rs763302617; called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
